Surgical pathology report (de-identified scan), TCGA case TCGA-50-5944, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-5944-01A (Primary Tumor).

PATIENT HISTORY:

PRE-OP DIAGNOSIS: Pulmonary nodule
POST-OP DIAGNOSIS: Same
PROCEDURE: Bronchoscopy; Biopsy; Lavage; Right video assisted thoracic surgery; Apical posterior segmentectomy with fiducials

FINAL DIAGNOSIS:

**PART 1: LUNG, RIGHT UPPER LOBE, BIOPSY –
BENIGN BRONCHIAL MUCOSA WITH MILD CHRONIC INFLAMMATION.**

**PART 2: LYMPH NODE, LEVEL 4, BIOPSY –
BENIGN LYMPH NODE FRAGMENT.**

**PART 3: LYMPH NODE, LEVEL 4R PRIME, BIOPSY –
BENIGN LYMPH NODE FRAGMENT.**

**PART 4: LYMPH NODE, LEVEL 10, BIOPSY –
BENIGN LYMPH NODE FRAGMENT.**

**PART 5: LYMPH NODE, LEVEL 4R PART C, BIOPSY –
BENIGN LYMPH NODE FRAGMENT.**

**PART 6: LYMPH NODE, LEVEL 7, BIOPSY –
BENIGN LYMPH NODE FRAGMENT.**

**PART 7: LYMPH NODE, LEVEL 7 PRIME, BIOPSY –
BENIGN LYMPH NODE FRAGMENT.**

**PART 8: LYMPH NODE, LEVEL 7C, BIOPSY –
BENIGN LYMPH NODE FRAGMENT.**

PART 9: LUNG, RIGHT APICAL POSTERIOR SEGMENT, SEGMENTECTOMY –
A. INVASIVE WELL-DIFFERENTIATED ADENOCARCINOMA, ACINAR TYPE WITH FOCAL BRONCHOALVEOLAR FEATURES, MEASURING 1.4 CM.
B. ALL SURGICAL MARGINS (BRONCHIAL, VASCULAR AND STAPLED MARGINS) ARE FREE OF TUMOR.
C. VISCERAL PLEURA IS FREE OF TUMOR.
D. NO DEFINITE LYMPHOVASCULAR SPACE PERMEATION SEEN.
E. OTHER FINDINGS INCLUDE APICAL CAP FIBROSIS, FOCAL SMALL PARENCHYMAL SCARS, AND MILD EMPHYSEMATOUS CHANGES.
F. AJCC PATHOLOGIC TUMOR STAGE: pT1 N0 MX.

**PART 10: BONE, FIFTH RIB, EXCISION –
BENIGN BONE.**

PART 11: LUNG, RIGHT, COMPLETION LOBECTOMY –
A. FOCAL SMALL PARENCHYMAL SCARS AND MILD EMPHYSEMATOUS CHANGES.
B. ALL SURGICAL MARGINS (BRONCHIAL, VASCULAR AND STAPLED MARGINS) ARE FREE OF TUMOR

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY LUNG TUMORS

TUMOR LOCATION: Right Upper Lobe
LUNG SEGMENT(S) INVOLVED: Apical
PROCEDURE: Lobectomy
TUMOR SIZE: Maximum dimension: 1.4 cm
Minor dimension: 1.0 cm

TUMOR TYPE: Invasive adenocarcinoma
HISTOLOGIC GRADE: G1, Well differentiated

**EXTRAPULMONARY PARENCHYMAL
EXTENSION/INVASION OF TUMOR:** None identified

ANGIOLYMPHATIC INVASION: No

TUMOR NECROSIS: < or = to 50%

SURGICAL MARGIN INVOLVEMENT: No

INFLAMMATORY(DESMOPLASTIC) REACTION: Mild

N1 LYMPH NODES: Number of N1 lymph nodes positive: 0

Number of N1 lymph nodes examined: 1

N2 LYMPH NODES: Number of N2 lymph nodes positive: 0

Number of N2 lymph nodes examined: 6

UNDERLYING DISEASE(S): Emphysema, Parenchymal scar, Other: Apical cap fibrosis.

T STAGE, PATHOLOGIC: pT1

N STAGE, PATHOLOGIC: pN0

M STAGE, PATHOLOGIC: pMX

Source: NCI Genomic Data Commons file d30efaf0-6943-4547-9a00-43129bab44eb (TCGA-50-5944.A3AD8013-B778-4FD0-9A5F-A516D6FF5A3E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).